Somatic mutation profile of tumor specimen MP2PRT-PASVHY-TMP1-A (aliquot MP2PRT-PASVHY-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASVHY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,608 days).
Specimen MP2PRT-PASVHY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be830a71-769d-4784-9dc3-18d711bb1693.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASVHY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASVHY-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/993dee28-eab4-4e77-8807-6782df271124

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Intron 2, Splice Region 2, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 32/270 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 25/418 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADAM19 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 85/266 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.769); catalogued as rs953465889; called by muse, mutect2, varscan2
- ADRB2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 139/409 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60005718; called by muse, mutect2, varscan2
- C4orf54 | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 19/584 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as rs980910690, COSV101552121; called by muse, mutect2
- COL19A1 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs373865939; called by muse, mutect2, varscan2
- CSF2RB | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 107/603 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.203); catalogued as COSV99453543; called by muse, mutect2, varscan2
- ERICH6B | c.855C>T p.A285= | Splice Region (SNP) | VAF 80/197 reads (41%) | catalogued as rs780308947; called by muse, mutect2, varscan2
- KCNC3 | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 94/694 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs780943930, COSV100979142; called by muse, mutect2, varscan2
- PGBD1 | c.2096C>T p.S699F | Missense Mutation (SNP) | VAF 39/443 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1476113310, COSV52556859; called by muse, mutect2
- SHROOM3 | c.2831G>A p.R944Q | Missense Mutation (SNP) | VAF 148/716 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); catalogued as rs145035894; called by muse, mutect2, varscan2
- TEX14 | c.2389C>T p.P797S (on ENST00000240361 / NM_001201457.2; = p.P791S on NM_031272.5) | Missense Mutation (SNP) | VAF 176/426 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544557607, COSV104383271; called by muse, mutect2, varscan2
- TMEM115 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 223/527 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99223420; called by muse, mutect2, varscan2
- TTN | c.49244G>A p.R16415Q (on ENST00000591111; = p.R8991Q on NM_003319.4) | Missense Mutation (SNP) | VAF 43/291 reads (15%) | PolyPhen benign (0.131); catalogued as rs376932266, COSV59983027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF263 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 128/407 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as rs1401168649; called by muse, mutect2
- BRD9 | c.400+1G>A p.X134_splice | Splice Site (SNP) | VAF 103/340 reads (30%) | called by muse, mutect2, varscan2
- LRIT2 | c.19T>C p.Y7H | Missense Mutation (SNP) | VAF 247/490 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4C11 | c.8A>C p.Q3P | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTUD5 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 87/651 reads (13%) | called by muse, mutect2, varscan2
- PRELID3A | c.294C>T p.I98= | Splice Region (SNP) | VAF 42/600 reads (7%) | called by muse, mutect2
- RLIM | c.472_473insGG p.P158Rfs*43 | Frame Shift Ins (INS) | VAF 53/335 reads (16%) | called by mutect2, pindel, varscan2
- SHROOM2 | c.3092G>A p.G1031E | Missense Mutation (SNP) | VAF 129/741 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TEX11 | c.2071G>A p.D691N (on ENST00000344304; = p.D676N on NM_031276.3) | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLG | c.6303G>A p.E2101= | Silent (SNP) | VAF 42/318 reads (13%) | called by muse, mutect2, varscan2
- KIF6 | c.936G>A p.G312= | Silent (SNP) | VAF 114/454 reads (25%) | called by muse, mutect2, varscan2
- MAGEC1 | c.1014C>T p.L338= | Silent (SNP) | VAF 80/264 reads (30%) | called by muse, varscan2
- PAPOLB | c.48G>A p.P16= | Silent (SNP) | VAF 110/584 reads (19%) | called by muse, mutect2, varscan2
- TAS2R1 | c.60G>A p.G20= | Silent (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- TBC1D30 | c.2430G>A p.V810= (on ENST00000542120; = p.V647= on NM_015279.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 184/538 reads (34%) | called by muse, mutect2, varscan2
- CAGE1 | c.2113-989A>T | Intron (SNP) | VAF 17/280 reads (6%) | called by muse, mutect2
- DST | c.4296+4245G>A | Intron (SNP) | VAF 54/384 reads (14%) | catalogued as rs1446480074, COSV55039516; called by muse, mutect2, varscan2
